Somatic mutation profile of cancer-model specimen HCM-BROD-0232-C25-85B (3D Organoid, passage 7; aliquot HCM-BROD-0232-C25-85B-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0232-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.8 years (27,330 days).
Specimen HCM-BROD-0232-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56cf8ede-814b-4fe7-b433-b25960401438.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0232-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0232-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ede6893a-d903-4627-a576-01456fab2ea0

The open-access MAF lists 63 somatic variants for this specimen: 50 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Nonsense Mutation 7, Splice Region 2, Splice Site 1, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGHM | c.777G>A p.W259* | Nonsense Mutation (SNP) | VAF 162/322 reads (50%) | catalogued as rs281865422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 172/392 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 168/357 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.4219G>A p.V1407I | Missense Mutation (SNP) | VAF 190/376 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.052); catalogued as rs747329081; called by muse, varscan2
- AZGP1 | c.336C>T p.N112= | Splice Region (SNP) | VAF 76/224 reads (34%) | catalogued as rs200393898; called by muse, mutect2
- CHST2 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 367/581 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58886185; called by muse, mutect2, varscan2
- COP1 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 148/362 reads (41%) | catalogued as COSV58176966; called by muse, mutect2, varscan2
- EFCAB11 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757985158, COSV50860774; called by muse, mutect2, varscan2
- ELFN2 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 181/565 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs759831341, COSV68746102, COSV68746173; called by muse, mutect2, varscan2
- ETV6 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 159/374 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765343; called by muse, mutect2, varscan2
- GPX5 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 188/306 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs1271480213; called by muse, mutect2, varscan2
- H3C13 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 556/771 reads (72%) | catalogued as rs1553754887; called by muse, mutect2, varscan2
- IQSEC3 | c.1256C>T p.T419M (on ENST00000538872 / NM_001170738.2; = p.T116M on NM_015232.1) | Missense Mutation (SNP) | VAF 161/713 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs1555087443, COSV100407812; called by muse, mutect2, varscan2
- KCNB2 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 267/512 reads (52%) | catalogued as COSV73053048; called by muse, mutect2, varscan2
- KIF4B | c.3266C>A p.S1089Y | Missense Mutation (SNP) | VAF 170/551 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV70527933; called by muse, mutect2, varscan2
- MACF1 | c.11771G>A p.R3924Q (on ENST00000372915; = p.R1857Q on NM_012090.5) | Missense Mutation (SNP) | VAF 77/243 reads (32%) | catalogued as rs753554779; called by muse, mutect2, varscan2
- MUC16 | c.23174C>T p.P7725L | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs566528880, COSV101198080, COSV67450285, COSV67480183; called by muse, varscan2
- MXRA5 | c.5839G>A p.V1947M | Missense Mutation (SNP) | VAF 405/406 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV54248924; called by muse, mutect2, varscan2
- NLRP3 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 116/341 reads (34%) | catalogued as rs746159202, COSV100275560, COSV60223782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPRL3 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 219/484 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs367729589, CM160810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2T3 | c.835G>T p.V279L | Missense Mutation (SNP) | VAF 268/893 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as COSV100613196, COSV62081711; called by muse, mutect2, varscan2
- P2RX3 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 108/445 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs369989085; called by muse, mutect2, varscan2
- SHANK3 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 145/398 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99436773; called by muse, mutect2, varscan2
- SIL1 | c.864+1G>A p.X288_splice | Splice Site (SNP) | VAF 169/276 reads (61%) | catalogued as COSV99498235; called by muse, mutect2, varscan2
- SLC36A2 | c.62T>C p.M21T | Missense Mutation (SNP) | VAF 221/356 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1411352793; called by muse, mutect2, varscan2
- SLC9C2 | c.2224A>T p.M742L | Missense Mutation (SNP) | VAF 231/565 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as rs1358768456; called by muse, mutect2, varscan2
- TP53 | c.370dup p.C124Lfs*25 | Frame Shift Ins (INS) | VAF 175/244 reads (72%) | catalogued as COSV52717910, COSV53118583; called by mutect2, pindel, varscan2
- ALAD | c.111C>T p.V37= | Splice Region (SNP) | VAF 95/325 reads (29%) | called by muse, mutect2, varscan2
- ATP1A1 | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP54 | c.2591C>G p.T864S | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- COG4 | c.1443G>T p.M481I | Missense Mutation (SNP) | VAF 351/621 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- CPEB4 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 130/423 reads (31%) | called by muse, mutect2, varscan2
- DDX43 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 285/285 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GRIA1 | c.1838G>T p.R613L | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- KIAA0586 | c.4438T>C p.C1480R (on ENST00000619416 / NM_001244190.2; = p.C1419R on NM_014749.5) | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KLF2 | c.11G>C p.S4T | Missense Mutation (SNP) | VAF 254/254 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LEMD3 | c.2483A>G p.N828S | Missense Mutation (SNP) | VAF 145/259 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MKI67 | c.2288T>G p.V763G | Missense Mutation (SNP) | VAF 190/383 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- NAP1L5 | c.541A>C p.K181Q | Missense Mutation (SNP) | VAF 117/462 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NIF3L1 | c.365G>T p.G122V (on ENST00000409020 / NM_001369444.1; = p.G95V on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 119/472 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- NWD2 | c.3493A>G p.S1165G | Missense Mutation (SNP) | VAF 225/426 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLA2G15 | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 447/764 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- POLR2H | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 75/282 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRT1B | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 184/600 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SIPA1L2 | c.4269G>C p.E1423D | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- SRSF1 | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 127/575 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TGFBR2 | c.561C>A p.Y187* | Nonsense Mutation (SNP) | VAF 351/352 reads (100%) | called by muse, mutect2, varscan2
- TSPAN13 | c.250_252del p.L84del | In Frame Del (DEL) | VAF 53/175 reads (30%) | called by mutect2, pindel, varscan2
- ZBED8 | c.1313A>T p.N438I | Missense Mutation (SNP) | VAF 155/247 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ZNF207 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 174/347 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANK1 | c.2568T>C p.S856= | Silent (SNP) | VAF 29/270 reads (11%) | catalogued as rs1242347468; called by muse, mutect2, varscan2
- IGHV1-46 | c.333C>T p.A111= | Silent (SNP) | VAF 85/180 reads (47%) | catalogued as rs782205579; called by muse, mutect2, varscan2
- KRTAP26-1 | c.381G>A p.P127= | Silent (SNP) | VAF 254/552 reads (46%) | catalogued as rs201629624, COSV62128773; called by muse, mutect2, varscan2
- LHX1 | c.474C>T p.S158= | Silent (SNP) | VAF 183/1115 reads (16%) | called by muse, mutect2, varscan2
- MPO | c.1014C>T p.D338= | Silent (SNP) | VAF 352/731 reads (48%) | catalogued as rs1163615061; called by muse, mutect2, varscan2
- NLGN4X | c.2055C>A p.L685= | Silent (SNP) | VAF 21/376 reads (6%) | called by muse, mutect2
- POTEI | c.267C>T p.S89= | Silent (SNP) | VAF 333/1141 reads (29%) | catalogued as rs765311760, COSV71576122; called by muse, varscan2
- RPUSD1 | c.691C>T p.L231= | Silent (SNP) | VAF 429/894 reads (48%) | catalogued as rs148818992; called by muse, mutect2, varscan2
- SLC6A2 | c.51G>A p.A17= | Silent (SNP) | VAF 323/613 reads (53%) | called by muse, mutect2, varscan2
- SVIL | c.5226C>T p.H1742= (on ENST00000355867 / NM_021738.3; = p.H1316= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 329/329 reads (100%) | catalogued as rs748042633, COSV63442487; called by muse, mutect2, varscan2
- WEE1 | c.456G>T p.R152= | Silent (SNP) | VAF 223/927 reads (24%) | called by muse, mutect2, varscan2
- ZNF483 | c.975G>A p.L325= | Silent (SNP) | VAF 88/299 reads (29%) | called by muse, mutect2, varscan2
- ABCB8 | c.-21C>T | 5'UTR (SNP) | VAF 128/406 reads (32%) | catalogued as rs373141641; called by muse, mutect2, varscan2
